Gene-level copy-number profile of tumor specimen TCGA-DX-A6YQ-01A from TCGA case TCGA-DX-A6YQ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 86.0 years (31,421 days).
Specimen TCGA-DX-A6YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.506360b4-12fc-46b3-9694-50388841a64a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b5e4a85-b011-44a3-85ea-468c9cc2e847

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,301; copy number 2: 25,217; copy number 3: 17,964; copy number 4: 11,674; copy number 5: 1,629; copy number 6: 1,129; copy number 7: 577; copy number 8: 274; copy number 10: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YQ-01A-12D-A33D-01): tumor purity 0.69, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:152,134,922–152,436,003, 4 genes (within-gene range 0–2): KMT2C, AC104692.2, AC104692.1, SEPTIN7P6.
- chr16:87,326,987–87,493,024, 7 genes (within-gene range 0–1): FBXO31, AC010531.5, MAP1LC3B, AC010531.3, ZCCHC14, AC105429.2, AC105429.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,408 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:61,481,087–72,282,539, 178 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:72,283,170–72,753,772, 1 gene, copy number 5 (within-gene range 3–5): AL513166.1.
- chr1:72,636,547–84,893,206, 157 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:167,430,640–167,914,215, 13 genes, copy number 6 (within-gene range 4–6): CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1.
- chr1:186,828,949–186,988,981, 1 gene, copy number 5: PLA2G4A.
- chr2:94,725,674–98,936,259, 152 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:103,855,829–104,147,229, 5 genes, copy number 6: AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1.
- chr2:106,933,739–107,407,329, 5 genes, copy number 6 (within-gene range 4–6): AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1.
- chr3:147,386,046–154,257,827, 132 genes, copy number 5 (broad region; genes not listed).
- chr3:156,825,481–158,545,730, 25 genes, copy number 5 (within-gene range 2–5): LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1, PTX3, SLC66A1L, AC084212.1, AC079943.2, RN7SKP46, AC079943.1, SHOX2, RSRC1, AC074276.1.
- chr4:68,784,618–81,215,117, 236 genes, copy number 5–7 (broad region; genes not listed).
- chr4:81,426,393–82,384,027, 12 genes, copy number 5 (within-gene range 1–5): RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, VAMP9P, AC124016.2, HNRNPD, AC124016.1.
- chr4:83,090,048–89,999,409, 113 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr4:91,319,034–92,184,052, 5 genes, copy number 5: AC074124.1, AC110774.1, KRT19P6, AC093810.1, PMPCAP1.
- chr4:93,820,171–93,830,964, 2 genes, copy number 5: RNA5SP164, ATOH1.
- chr6:81,724,722–86,436,138, 63 genes, copy number 6 (broad region; genes not listed).
- chr6:87,826,173–90,587,072, 51 genes, copy number 5: Y_RNA, RN7SL183P, AL590392.1, AL136096.1, SPACA1, CNR1, AL121835.2, AL139042.1, AL121835.1, ACTBP8, AL139090.1, RNGTT, SNORA73, AL079342.3, AL079342.1, AL079342.2, RNU2-61P, AL353135.1, PNRC1, RN7SL336P, SRSF12, AL353135.2, PM20D2, GABRR1, GABRR2, TUBB3P1, UBE2J1, RRAGD, NACAP7, ANKRD6, RN7SL11P, AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7.
- chr6:96,924,620–100,890,338, 37 genes, copy number 6 (within-gene range 2–6): KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2.
- chr6:113,791,829–120,015,257, 81 genes, copy number 5–6 (broad region; genes not listed).
- chr6:123,216,339–123,637,093, 2 genes, copy number 5 (within-gene range 3–5): TRDN, TRDN-AS1.
- chr9:128,340,527–129,513,687, 60 genes, copy number 5: SLC27A4, TMSB4XP4, URM1, AL359091.1, MIR219A2, MIR219B, CERCAM, AL359091.4, AL359091.2, ODF2, ODF2-AS1, GLE1, AL356481.1, RNU7-171P, SPTAN1, AL356481.2, AL356481.3, DYNC2I2, VTI1BP4, HMGA1P4, SET, PKN3, RN7SL560P, ZDHHC12, AL441992.1, ZER1, Metazoa_SRP, TBC1D13, ENDOG, SPOUT1, AL441992.2, KYAT1, LRRC8A, PHYHD1, AL672142.1, DOLK, NUP188, AL592211.1, SH3GLB2, MIGA2, AL592211.2, DOLPP1, CRAT, AL158151.2, PTPA, AL158151.3, AL158151.4, IER5L, AL158151.1, AL161785.1, C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2.
- chr12:127,914,707–132,363,348, 126 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:105,300,563–106,875,071, 211 genes, copy number 5 (broad region; genes not listed).
- chr16:63,314,264–63,618,046, 1 gene, copy number 5 (within-gene range 4–5): AC138305.1.
- chr16:63,703,483–64,343,909, 6 genes, copy number 5: AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1.
- chr17:8,729,935–22,706,703, 502 genes, copy number 5–7 (broad region; genes not listed).
- chr17:45,585,871–46,028,334, 16 genes, copy number 7 (within-gene range 4–7): DND1P1, AC126544.2, AC126544.1, MAPK8IP1P2, RPS26P8, LINC02210, LINC02210-CRHR1, AC217774.1, AC217774.2, CRHR1, MAPT-AS1, SPPL2C, MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP.
- chr17:46,193,576–46,268,694, 5 genes, copy number 6: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr17:74,521,174–79,850,110, 229 genes, copy number 6 (broad region; genes not listed).
- chr17:80,260,866–80,398,786, 1 gene, copy number 6 (within-gene range 4–6): RNF213.
- chr17:80,333,841–81,183,166, 33 genes, copy number 6 (within-gene range 2–6): AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31, RPTOR, RPL31P7, AC016245.1, AC016245.2, AC127496.3, AC127496.4, AC127496.1, RPL12P37, CHMP6, AC127496.6, AC127496.7, AC127496.5, AC127496.2, BAIAP2-DT, BAIAP2, AATK, MIR657, MIR3065, MIR338, MIR1250, AC115099.1, PVALEF.
- chr19:27,638,483–34,229,515, 140 genes, copy number 5–8 (broad region; genes not listed).
- chr19:38,303,558–42,069,498, 215 genes, copy number 8 (broad region; genes not listed).
- chr20:50,794,894–62,296,213, 194 genes, copy number 5–6 (broad region; genes not listed).
- chr22:15,290,718–21,081,018, 276 genes, copy number 6 (broad region; genes not listed).
- chr22:36,281,280–36,387,967, 1 gene, copy number 10 (within-gene range 2–10): MYH9.
- chr22:36,335,421–37,035,513, 28 genes, copy number 10: Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1, AL022313.3, CACNG2, AL022313.4, AL049749.1, Z80897.2, IFT27, Z80897.1, PVALB, Z82185.1, NCF4-AS1, NCF4, CSF2RB, CSF2RBP1, LL22NC01-81G9.3, TEX33, TST, Y_RNA, MPST, Z73420.1.
- chr22:40,673,484–42,649,392, 93 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,293. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
